Gene-level copy-number profile of tumor specimen TCGA-16-0861-01A from TCGA case TCGA-16-0861, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,778 days).
Specimen TCGA-16-0861-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.2b773bf3-0849-4f54-a443-b8bb2f3b3bd0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-16-0861-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71ee0216-121a-451c-b0fc-12e5e9280daf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 10,205; copy number 2: 47,088; copy number 3: 2,398; copy number 40: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-16-0861-01A-01D-0384-01): tumor purity 0.88, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:34,657,606–34,714,598, 2 genes (within-gene range 0–2): AC093689.1, AC093913.1.
- chr9:19,507,452–26,644,595, 98 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–55,595,006, 23 genes, copy number 40 (within-gene range 3–40): LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.

Autosomal genes at a single copy (total copy number 1): 7,818. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
